TARGET case TARGET-00-RO02211 — Acute Myeloid Leukemia (TARGET-AML)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/cddedaee-0c27-4073-b5ce-6fa427e59f7a

Biospecimens (1 sample)
- Sample TARGET-00-RO02211-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
